Gene-level copy-number profile of tumor specimen ALCH-B1T6-TTP1-A from ALCHEMIST case ALCH-B1T6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 68.8 years (25,118 days).
Specimen ALCH-B1T6-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 676418d4-7190-4ed2-b97e-a67617f2dc50.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1T6-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,243 have no estimate.
https://portal.gdc.cancer.gov/files/d3da4e1c-4558-4e5e-b469-c8800748c76c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 1,132; copy number 2: 55,831; copy number 3: 1,240; copy number 4: 86; copy number 5: 1; copy number 6: 1; copy number 7: 53; copy number 13: 1; copy number 18: 1.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:49,162,535–49,176,486, 2 genes: CCDC71, KLHDC8B.
- chr5:135,802,985–135,803,075, 1 gene: MIR5692C1.
- chr6:33,694,293–33,711,727, 2 genes (within-gene range 0–2): UQCC2, MIR3934.
- chr8:22,024,125–22,048,809, 2 genes: NPM2, FGF17.
- chr10:5,594,984–5,632,566, 1 gene (within-gene range 0–2): LASTR.
- chr11:1,274,371–1,309,654, 1 gene: TOLLIP.
- chr11:3,225,030–3,232,838, 2 genes: MRGPRE, AC109309.1.
- chr11:17,392,498–17,492,367, 3 genes: ABCC8, SDHCP4, AC124798.3.
- chr11:48,959,928–48,983,826, 2 genes: AC027369.2, TRIM51GP.
- chr12:30,978,308–31,006,010, 1 gene (within-gene range 0–2): AC008013.1.
- chr15:25,194,921–25,208,163, 8 genes (within-gene range 0–2): SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21.
- chr16:53,828–57,669, 1 gene: SNRNP25.
- chr16:67,277,510–67,289,499, 1 gene (within-gene range 0–2): PLEKHG4.
- chr17:2,337,498–2,381,058, 3 genes (within-gene range 0–2): SGSM2, AC006435.3, AC006435.2.
- chr17:80,200,673–80,205,949, 1 gene (within-gene range 0–2): AC087741.1.
- chr22:38,424,288–38,455,199, 3 genes: Z97056.1, KCNJ4, Z97056.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 57 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:68,683,779–70,436,584, 53 genes, copy number 7: GAL, TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr14:18,333,726–18,341,859, 1 gene, copy number 6: CR383658.1.
- chr14:18,395,626–18,412,264, 1 gene, copy number 5: CR383658.2.
- chr21:43,140,523–43,141,092, 1 gene, copy number 13: FRGCA.
- chr21:43,169,008–43,172,805, 1 gene, copy number 18: CRYAA.

Autosomal genes at a single copy (total copy number 1): 1,125. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
